CPTAC case C3L-08296 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c785439-10fa-4810-9992-6fee541b7f31

Demographics
Sex at birth: female; Race: white; Year of birth: 1963; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Gastric antrum; Age at diagnosis: 59.5 years (21,715 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Residual disease: R0; Days to last known disease status: 637 days (1.7 years); Progression or recurrence: no; Days to last follow up: 637 days (1.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 57 days; Days to treatment end: 78 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 63 days; Days to treatment end: 223 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Fluorouracil; Days to treatment start: 63 days; Days to treatment end: 223 days; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 310 days; Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 637 days (1.7 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 28; Cigarettes per day: 20; Tobacco smoking onset year: 1978; Tobacco smoking quit year: 2006; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 28.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08296-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 535 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08296-23: Section location: Antrum; Percent tumor nuclei: 50; Percent necrosis: 5.
- Sample C3L-08296-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 7 days; Method of sample procurement: Blood Draw.
